Somatic mutation profile of tumor specimen TCGA-55-8512-01A (aliquot TCGA-55-8512-01A-11D-2393-08) from TCGA case TCGA-55-8512, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.8 years (15,266 days).
Specimen TCGA-55-8512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a271f82-7006-4b6e-bc5e-8eb8138d7cd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8512-10A (Blood Derived Normal), aliquot TCGA-55-8512-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d970f54-4b95-42c1-8349-2b48e74840df

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374492515; called by muse, mutect2, varscan2
- ACTRT1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs765631534, COSV100947563; called by muse, mutect2, varscan2
- CADPS | c.1490T>C p.M497T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99337559; called by muse, mutect2, varscan2
- CERT1 | c.1861C>G p.Q621E (on ENST00000405807 / NM_001130105.1; = p.Q493E on NM_005713.3) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99783150; called by muse, mutect2, varscan2
- CNOT1 | c.5285C>A p.A1762D | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99799964; called by muse, mutect2, varscan2
- CSMD1 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101219667; called by muse, mutect2, varscan2
- CSMD3 | c.7580C>A p.S2527Y (on ENST00000297405 / NM_001363185.1; = p.S2423Y on NM_052900.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV52231979, COSV99830652; called by muse, mutect2, varscan2
- DST | c.20160G>T p.W6720C (on ENST00000361203 / NM_001374722.1; = p.W4417C on NM_015548.5) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752791, COSV99754632; called by muse, mutect2, varscan2
- GDF10 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs782356398; called by muse, mutect2, varscan2
- KIAA0319 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296675464, COSV65501662; called by muse, mutect2, varscan2
- NBEA | c.3683C>T p.S1228L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100079137, COSV59779897; called by muse, mutect2
- NFE2L3 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV50241681, COSV99283647; called by muse, mutect2, varscan2
- P2RX6 | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100298666; called by muse, mutect2, varscan2
- PLSCR5 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV101494481; called by muse, mutect2, varscan2
- PRB2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 65/386 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV66984168; called by muse, varscan2
- PRLR | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV99184331; called by muse, mutect2, varscan2
- PTER | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100126635; called by muse, mutect2
- RALGAPB | c.3835A>G p.N1279D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs781384332, COSV99485091; called by muse, mutect2, varscan2
- RIMS2 | c.960C>G p.Y320* (on ENST00000666250 / NM_001348490.2; = p.Y128* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV51715692; called by muse, mutect2, varscan2
- SERGEF | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV99787154; called by muse, mutect2, varscan2
- SLC4A10 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs867008585, COSV99763519; called by muse, mutect2, varscan2
- SON | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99277862; called by muse, mutect2, varscan2
- TBX18 | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV100858494; called by muse, mutect2, varscan2
- TLL1 | c.1097C>G p.P366R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99286950; called by muse, mutect2, varscan2
- TLN2 | c.555A>T p.Q185H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168757; called by muse, mutect2, varscan2
- TMC2 | c.1491C>G p.H497Q | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100727528; called by muse, mutect2, varscan2
- TOP1 | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV100793783; called by muse, mutect2, varscan2
- USP32 | c.4082G>A p.S1361N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV100341851; called by muse, mutect2, varscan2
- FBXL16 | c.668_671del p.L223Rfs*17 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- PEG3 | c.3424_3425del p.H1142Ffs*22 | Frame Shift Del (DEL) | VAF 26/192 reads (14%) | called by pindel, varscan2
- ARHGAP45 | c.1881G>A p.S627= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100491042, COSV57431266; called by muse, mutect2, varscan2
- CCDC183 | c.591G>A p.V197= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs1406133591, COSV100565989; called by muse, mutect2, varscan2
- FGF21 | c.607C>A p.R203= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV55811334, COSV99711434; called by muse, mutect2
- LPIN1 | c.1434C>T p.I478= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99877427; called by muse, mutect2
- NTN1 | c.576C>T p.P192= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV51478035; called by muse, mutect2
- OR4B1 | c.345G>T p.V115= | Silent (SNP) | VAF 35/203 reads (17%) | catalogued as COSV100535574; called by muse, mutect2, varscan2
- PRLR | c.468G>T p.L156= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV99184326; called by muse, mutect2, varscan2
- SLC39A12 | c.1224C>A p.A408= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV66199918; called by muse, mutect2, varscan2
- STIL | c.1548C>T p.P516= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as rs375423064, COSV99680850; called by muse, mutect2, varscan2
- TLL1 | c.1098C>A p.P366= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99286953; called by muse, mutect2, varscan2
- TMIGD2 | c.756C>A p.P252= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100010224, COSV56667219; called by muse, mutect2, varscan2
